Somatic mutation profile of tumor specimen MBCProject_2076_T1_WES (aliquot MBCProject_2076_T1_WES_1) from CMI case MBCProject_2076, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 35.0 years (12,800 days).
Specimen MBCProject_2076_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a874787-7a1c-46e6-a7b6-ee14db7e6ac8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2076_SALIVA (Saliva), aliquot MBCProject_2076_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1e4af58-d679-4ff7-9d93-723703d974d1

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 1, Nonsense Mutation 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC6 | c.1288G>A p.V430M (on ENST00000392336; = p.V405M on NM_033415.4) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs369392289; called by muse, mutect2, varscan2
- IL21 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as rs1182579210; called by muse, mutect2, varscan2
- MAP2K4 | c.815C>G p.P272R | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62255417; called by muse, mutect2, varscan2
- SLFNL1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1296939514; called by muse, mutect2
- TMEM126A | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150267785; called by muse, mutect2, varscan2
- ZNF606 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100071904, COSV58704958; called by muse, mutect2
- ADAMTS6 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- AFG3L2 | c.1468C>A p.H490N | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2
- ASB7 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 33/446 reads (7%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.728); called by muse, mutect2
- CYP20A1 | c.1057A>T p.I353F | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2
- ZNF354C | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 30/283 reads (11%) | called by muse, mutect2, varscan2
- CCER1 | c.444C>T p.R148= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV62646982; called by muse, mutect2, varscan2
- PATJ | c.5253C>T p.Y1751= | Silent (SNP) | VAF 43/272 reads (16%) | catalogued as rs41305852; called by muse, mutect2, varscan2
- RHOG | c.324G>T p.V108= | Silent (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2, varscan2
- STAT5A | c.540G>A p.L180= | Silent (SNP) | VAF 31/442 reads (7%) | called by muse, mutect2
- ZP3 | c.168C>T p.S56= (on ENST00000394857 / NM_001110354.2; = p.S5= on NM_007155.6) | Silent (SNP) | VAF 32/320 reads (10%) | called by muse, mutect2
- ALK | c.3516-316C>T | Intron (SNP) | VAF 23/271 reads (8%) | catalogued as rs958795504; called by muse, mutect2
- IFIT5 | c.-43C>T | 5'UTR (SNP) | VAF 9/247 reads (4%) | called by muse, mutect2
- XIAP | c.*5664A>G | 3'UTR (SNP) | VAF 8/222 reads (4%) | catalogued as rs1256618390; called by muse, mutect2
